Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-7072, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-7072-01A (Primary Tumor).

[page 1 of 6]
Patient Name	MRN	Visit Number

Event Date and Time	Procedure Ordered	Status	Ordered By	Specimen #
	Surgical Pathology Report	supplemental		
Collection Date:				
Accession Date:				
Result Date:				

Surgical Pathology Consultation Report

* Addended *

SPECIMEN(S) RECEIVED

1. Nck: RT.neck level 2B
2. Neck: Right neck level II
3. Neck: Right neck level III
4. Neck: Right neck level IV
5. Neck: Right neck level I
5. Soft Tissue: Right partial glossectomy and right partial mandibulectomy -
7. Neck: Left neck level I, II
3. Oral Cavity: Left floor of mouth -
9. Soft Tissue: Left sublingual gland -
10. Soft Tissue: Left ventral tongue -
11. Soft Tissue: Deep tongue margin -
12. Soft Tissue: Right tongue margin -
13. Soft Tissue: Deep midline muscle -
14. Surgical Waste

DIAGNOSIS

1. Right neck level IIB.
Six lymph nodes negative for tumor (0/6).
2. Right neck level II.
Four lymph nodes negative for tumor (0/4).
3. Right neck level III.
Soft tissues with no pathologic changes.
No lymph nodes present.
4. Right neck level IV.
Eight lymph nodes negative for tumor (0/8).
5. Right neck level I.
Two lymph nodes negative for tumor (0/2).
Submandibular gland with moderate atrophy. Negative for tumor.

[page 2 of 6]
6. Oral cavity; tongue; right partial glossectomy and right partial mandibulectomy.
- Squamous cell carcinoma, moderately differentiated.
- a. Tumor maximum diameter 3.2 cm.
- b. Tumor thickness 1.2 cm.
- c. Extensive perineural invasion is present.
- d. No lymphatic/vascular invasion.
- e. The lateral margin is close (0.3 cm) to tumor. The remaining margins are negative for tumor.
- f. Squamous carcinoma in-situ is also present.
- g. Sections of the mandible are pending. An addendum report will follow.
7. Left neck level I and II.
- Eight lymph nodes negative for tumor (0/8).
- Submandibular gland with no pathologic changes. Negative for tumor.
8. Left floor of mouth.
- Negative for tumor.
9. Left sublingual gland.
- Sublingual gland with no pathologic changes.
10. Left ventral tongue.
- Negative for tumor.
11. Deep tongue margin.
- Negative for tumor.
12. Right tongue margin.
- Negative for tumor.
13. Deep midline muscle.
- Negative for tumor.
14. Surgical waste.
- Bone and soft tissues with no pathologic changes. (Gross examination only)

SYNOPTIC DATA

Specimen Type: Resection:right partial glossectomy and right partial mandibulectomy.

Tumor Site: Tongue

Histologic Type: Squamous cell carcinoma, conventional

Tumor Size: Greatest dimension: 3.2 cm

Tumor thickness: 1.2 cm

Histologic Grade: G3: Poorly differentiated

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Perineural Invasion: Present

[page 3 of 6]
Additional Pathologic Findings: Carcinoma in situ

Margins: Margins uninvolved by tumor

Margins uninvolved by tumor - Distance of tumor from closest margin: 0.3 cm

Margins: lateral

Pathologic Staging (pTNM): pT2: Tumor of lip or oral cavity more than 2 cm but not more than 4 cm in greatest dimension

pN0: No regional lymph node metastasis for aerodigestive sites

Number of regional lymph nodes examined: 28

Number of regional lymph nodes involved: 0

pMX: Distant metastasis cannot be assessed

ELECTRONICALLY VERIFIED

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and "Neck: Right neck level I B". It consists of portion of fibroadipose tissue measuring 3.0 x 3.0 x 1.5 cm. Multiple lymph nodes ranging from 0.8 to 1.5 cm are identified. Representative sections are submitted.

1A-1B one lymph node each

1C four lymph nodes

2. The specimen is labeled with the patient's name and "Neck: Right neck level I". It consists of portion of fibroadipose tissue measuring 3.0 x 2.5 x 1.0 cm. Multiple lymph nodes ranging from 0.4 to 1.2 cm are identified. Representative sections are submitted.

2A one lymph node

2B multiple lymph nodes

3. The specimen is labeled with the patient's name and "Neck: Right neck level II". It consists of portion of fibroadipose tissue measuring 3.5 x 3.0 x 2.5 cm. No lymph nodes are identified.

3A representative sections

4. The specimen is labeled with the patient's name and "Neck: Right neck level V". It consists of portion of fibroadipose tissue measuring 3.5 x 3.0 x 1.5 cm. Multiple lymph nodes ranging from 0.3 to 1.2 cm are identified. Representative sections are submitted.

4A-4B multiple lymph nodes each

5. The specimen is labeled with the patient's name and "Neck: Right neck level

[page 4 of 6]
I". It consists of portion of fibroadipose tissue and submandibular gland measuring 4.5 x 3.7 x 2.4 cm. The submandibular gland measures 3.7 x 2.5 x 1.2 cm and is unremarkable. Multiple lymph nodes ranging from 1.0 to 1.5 cm are identified. Representative sections are submitted.

5A submandibular gland

5B two lymph nodes

5C one lymph node

6. The specimen is labeled the patient's name and "Soft Tissue: Right partial glossectomy and right partial mandibulectomy- ". It consists of an oriented portion of right tongue, floor of mouth, and a segment of mandible with overall dimensions of 4.3 SI x 6.5 ML x 6.0 AP cm. The tongue measures 5.5 x 3.5 x 1.1 cm. The floor of mouth measures 4.7 x 2.0 x 0.5 cm. The mandible consists of the body and ascending ramus and measures 7.5 by 3.0 x 0.8 cm. The mandible contains one tooth. There is an ill-defined tumor involving the tongue, and floor of mouth . The tumor measures 3.2 x 2.2 x 1.2 cm. The tumor is solid, and has a yellow-tan cut surface. No invasion of bone is identified. It is located at 0.3 cm from the lateral margin, 2.0 cm from the medial margin, 0.8 cm from the deep margin, 0.3 cm from the anterior margin, and 1.2 cm from the posterior margin. A representative section of tumor with deep margin is submitted for frozen section. The deep/medial margin is painted with silver nitrate and India ink. The distance from the tumor to the is 0.8 cm. Two pieces of tumor and normal tissue were taken for the tissue bank. Sections of bone are taken for decalcification. Representative sections are submitted.

6A frozen section control

6B anterior margin

6C lateral margin

6D posterior margin

6E medial margin

6F-6H tumor with deep margin

6I tumor

6J normal tongue

6K anterior mandible margin

6L posterior mandible margin

6M-6O mandible closest to tumor

7. The specimen is labeled with the patient's name and "Neck: Left neck, level I, II". It consists of portion of fibroadipose tissue and submandibular gland measuring 6.0 x 5.0 x 2.5 cm. The submandibular gland measures 4.8 x 3.5 x 1.8 cm and is unremarkable. Multiple lymph nodes ranging from 0.3 to 1.5 cm are identified. Representative sections are submitted.

7A submandibular gland

7B multiple lymph nodes level I

[page 5 of 6]
7C multiple lymph nodes level II

8. The specimen is labeled with the patient's name and "Oral Cavity: Left floor of mouth- ". It consists of a fragment of tissue measuring 2.5 x 0.2 x 0.1 cm. The specimen is submitted in toto for frozen section.

8A frozen section control

9. The specimen is labeled with the patient's name and "Soft Tissue: Left sublingual gland- ". It consists of a fragment of tissue measuring 1.7 x 1.5 x 0.7 cm. The specimen is submitted in toto for frozen section.

9A frozen section control

10. The specimen is labeled with the patient's name and "Soft Tissue: Left ventral tongue- ". It consists of a fragment of tissue measuring 2.0 x 0.2 x 0.2 cm. The specimen is submitted in toto for frozen section.

10A frozen section control

11. The specimen is labeled with the patient's name and "Soft Tissue: Deep tongue margin". It consists of a fragment of tissue measuring 0.4 x 0.3 x 0.1 cm. The specimen is submitted in toto for frozen section.

11A frozen section control

12. The specimen is labeled with the patient's name and "Soft Tissue: Right tongue margin- ". It consists of a fragment of tissue measuring 1.5 x 0.5 x 0.3 cm. The specimen is submitted in toto for frozen section.

12A frozen section control

13. The specimen is labeled with the patient's name and "Soft Tissue: Deep midline muscle- ". It consists of a fragment of tissue measuring 1.6 x 0.7 x 0.6 cm. The specimen is submitted in toto for frozen section.

13A frozen section control

14. The specimen is labeled with the patient's name and "Surgical Waste". It consists of four pieces of unremarkable yellow-tan bone tissue with minimal soft tissue ranging in size from 1.5 x 0.7 x 0.2 cm to 6.5 x 2.0 x 1.2 cm. No sections are submitted for microscopic examination.

QUICK SECTION

6A. Right glossectomy specimen; deep margin (taken with surgery fellow);
- Squamous cell carcinoma, present more than 0.5 cm from inked deep margin.

8A-13A. Margins (left floor of mouth, left sublingual, left ventral tongue, deep tongue, right tongue, deep midline muscle);
- Negative for malignancy.

Called at

[REDACTED]

Addendum Status: Signed Out

[REDACTED]

[page 6 of 6]
Addendum Comment

Decalcified sections of the mandible show invasion of cortical bone by squamous cell carcinoma. The bone margins are negative for carcinoma.

Source: NCI Genomic Data Commons file b0a6afdb-2516-4347-bcf0-efb7cc853b5a (TCGA-CQ-7072.75642D9B-7F8C-4E99-A19C-B610D21BFACD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).